Somatic mutation profile of tumor specimen TCGA-ED-A82E-01A (aliquot TCGA-ED-A82E-01A-11D-A34Z-10) from TCGA case TCGA-ED-A82E, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 60.9 years (22,234 days).
Specimen TCGA-ED-A82E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80fb49f1-5f79-4c83-a242-66f92696e76b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A82E-10A (Blood Derived Normal), aliquot TCGA-ED-A82E-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7aa93ac-9efd-4d48-a889-9dd76b436f13

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 20, Silent 10, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 45/93 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADIPOR2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs750803822, COSV63945473; called by muse, mutect2, varscan2
- ADRM1 | c.745G>C p.G249R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.724); catalogued as COSV53370786; called by muse, mutect2, varscan2
- EIF3H | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs755682334, COSV52671581; called by muse, mutect2, varscan2
- FOXP2 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.678); catalogued as COSV63492984; called by muse, mutect2, varscan2
- METTL17 | c.1265+7G>T | Splice Region (SNP) | VAF 11/41 reads (27%) | catalogued as COSV53870925; called by muse, mutect2, varscan2
- MORN5 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs762113900, COSV65648618; called by muse, mutect2, varscan2
- OR10G7 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 97/299 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV57868711; called by muse, mutect2, varscan2
- PAPPA | c.3946C>T p.H1316Y | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV60290542; called by muse, mutect2, varscan2
- PCDH11X | c.1105G>T p.V369F | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV100012131; called by muse, mutect2, varscan2
- PMM1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1199024885, COSV53449243; called by muse, mutect2, varscan2
- POLD1 | c.2280G>T p.M760I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70957024; called by muse, mutect2, varscan2
- PTPRN2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.221); catalogued as COSV67058197; called by muse, mutect2, varscan2
- RCN3 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54543671; called by muse, mutect2, varscan2
- SART1 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs1455403613, COSV56710386; called by muse, mutect2, varscan2
- SLF1 | c.2078G>T p.S693I | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV54373000; called by muse, mutect2
- SLITRK5 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs372673658; called by muse, mutect2, varscan2
- SPPL2A | c.467T>G p.I156S | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV55943063; called by muse, mutect2, varscan2
- STXBP5L | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757487745, COSV56519058; called by muse, mutect2, varscan2
- TBC1D26 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.643); catalogued as rs769403998, COSV68610860; called by muse, mutect2, varscan2
- USP34 | c.7967C>T p.A2656V | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as rs375628616; called by muse, mutect2, varscan2
- CD81 | c.424_425dup p.N142Kfs*7 | Frame Shift Ins (INS) | VAF 25/60 reads (42%) | called by mutect2, pindel, varscan2
- MED29 | c.309_318dup p.T107Dfs*5 (on ENST00000615911; = p.T86Dfs*5 on NM_017592.4) | Frame Shift Ins (INS) | VAF 19/52 reads (37%) | called by mutect2, varscan2
- ARHGAP22 | c.1428G>A p.S476= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs1337533758, COSV99985391; called by muse, mutect2
- DYTN | c.1182A>G p.Q394= | Silent (SNP) | VAF 70/120 reads (58%) | catalogued as COSV71752900; called by muse, varscan2
- FPR1 | c.321C>A p.I107= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV59050921; called by muse, mutect2, varscan2
- PCDH12 | c.426G>T p.L142= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV51524136; called by muse, mutect2, varscan2
- SPAG5 | c.2877G>A p.Q959= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1437169387, COSV56887329; called by muse, mutect2, varscan2
- SPTBN1 | c.2778C>T p.I926= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV61693255; called by muse, mutect2, varscan2
- TNN | c.522G>A p.A174= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs374925420; called by muse, mutect2, varscan2
- XYLT1 | c.669C>T p.A223= | Silent (SNP) | VAF 65/145 reads (45%) | catalogued as rs772956681, COSV54484738, COSV54495200; called by muse, mutect2, varscan2
- ZBBX | c.2190C>T p.S730= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV56799569; called by muse, mutect2, varscan2
- ZNF311 | c.780A>C p.S260= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as COSV65853368; called by muse, mutect2, varscan2
